MMRF case MMRF_1580 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dba0dea2-ebf3-4222-a01e-bf6041d7ba8b

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 123 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.0 years (23,388 days); ISS stage: II; Days to last known disease status: 123 days; Days to last follow up: 123 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 70 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 81 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 123.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 466 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 54.8 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.89 µg/mL; Hemoglobin 5.52 mmol/L; Leukocytes 18 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 911 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.2 mmol/L; Albumin 24 g/L; Glucose 4.4 mmol/L; C-Reactive Protein 0.422 mg/dL.
- Day 81 (ECOG 3): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 899 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 37.7 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.46 mmol/L; Leukocytes 24.2 ×10⁹/L; Absolute Neutrophil 21.5 ×10⁹/L; Platelets 344 ×10⁹/L; Creatinine 374 µmol/L; Blood Urea Nitrogen 42 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 7.5 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day -3: Weight: 82 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1580_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1580_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
